CCDI case PBBXRV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/f2e536dc-d745-49fe-829c-2e0608b9f4ce

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.1 years (3,322 days).

Biospecimens (3 samples)
- Sample 0DK0AD: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DK0AK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DK0AR: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
